Somatic mutation profile of tumor specimen MP2PRT-PAUPUG-TMP1-A (aliquot MP2PRT-PAUPUG-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUPUG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 6.8 years (2,467 days).
Specimen MP2PRT-PAUPUG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4313c2d0-8c25-4894-87bf-a14a8d7170bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPUG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPUG-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6c05413-7371-4c04-8617-525d6dbd99c6

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 15, Frame Shift Ins 2, 3'Flank 2, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 35/155 reads (23%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 38/213 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 140/280 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs1321489314; called by muse, mutect2, varscan2
- ANKRD13B | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 105/214 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759722370; called by muse, mutect2, varscan2
- BMP15 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 190/641 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782405435; called by muse, mutect2, varscan2
- CCR7 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs1469701969, COSV55848542; called by muse, mutect2, varscan2
- CPXCR1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 131/445 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.57); catalogued as COSV52161262; called by muse, mutect2, varscan2
- CREBBP | c.1108_1109insATTC p.R370Hfs*58 | Frame Shift Ins (INS) | VAF 24/123 reads (20%) | catalogued as COSV52117504, COSV52129464; called by mutect2, pindel*, varscan2
- FAM47A | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 266/963 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1200250652, COSV60497293; called by muse, mutect2, varscan2
- FGF12 | c.359G>A p.G120E (on ENST00000454309 / NM_021032.5; = p.G58E on NM_004113.6) | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53164172; called by muse, mutect2, varscan2
- MYO6 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1303908885, COSV64118608; called by muse, mutect2, varscan2
- NR3C2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 82/297 reads (28%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.796); catalogued as rs1406792251; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 59/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5C | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774148486, COSV71657935; called by muse, mutect2, varscan2
- VSTM4 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 149/510 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs776872945; called by muse, mutect2, varscan2
- ALS2 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 107/260 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- B3GALNT1 | c.855A>T p.E285D | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CNGB1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CROCC2 | c.3500G>A p.R1167K | Missense Mutation (SNP) | VAF 117/226 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DCDC1 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ETV6 | c.1218_1220del p.I407del | In Frame Del (DEL) | VAF 19/174 reads (11%) | called by mutect2, pindel, varscan2
- FOLH1 | c.485G>C p.S162T | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAOA | c.954G>A p.K318= | Splice Region (SNP) | VAF 68/198 reads (34%) | called by muse, mutect2, varscan2
- MAOA | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHAC1 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 111/271 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PRSS12 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 189/632 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFAP2D | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 159/467 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZBTB7B | c.1381_1384dup p.R462Pfs*59 (on ENST00000292176; = p.R496Pfs*59 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 176/435 reads (40%) | called by mutect2, pindel, varscan2
- APOB | c.5109C>T p.A1703= | Silent (SNP) | VAF 37/414 reads (9%) | catalogued as rs535176100, COSV51930190; called by muse, mutect2
- ARHGEF11 | c.363C>T p.G121= | Silent (SNP) | VAF 110/260 reads (42%) | called by muse, mutect2, varscan2
- DAAM2 | c.1782G>A p.R594= | Silent (SNP) | VAF 169/481 reads (35%) | catalogued as COSV51372443; called by muse, mutect2, varscan2
- DEFB125 | c.183A>T p.S61= | Silent (SNP) | VAF 55/201 reads (27%) | called by muse, mutect2, varscan2
- DOP1B | c.6741C>T p.F2247= | Silent (SNP) | VAF 168/755 reads (22%) | catalogued as COSV67690691; called by muse, mutect2, varscan2
- FAT4 | c.7524G>A p.S2508= | Silent (SNP) | VAF 124/438 reads (28%) | catalogued as rs1304373442, COSV58672805; called by muse, mutect2, varscan2
- FOXL3 | c.114C>T p.I38= | Silent (SNP) | VAF 83/175 reads (47%) | called by muse, mutect2, varscan2
- JAML | c.618G>A p.V206= (on ENST00000356289 / NM_001098526.2; = p.V196= on NM_153206.3) | Silent (SNP) | VAF 113/252 reads (45%) | called by muse, mutect2, varscan2
- LRP1 | c.6271C>T p.L2091= | Silent (SNP) | VAF 97/213 reads (46%) | catalogued as COSV99676852; called by muse, mutect2, varscan2
- MMP15 | c.405C>T p.T135= | Silent (SNP) | VAF 90/226 reads (40%) | catalogued as rs146192273; called by muse, mutect2, varscan2
- NPS | c.201G>A p.V67= | Silent (SNP) | VAF 119/426 reads (28%) | called by muse, mutect2, varscan2
- NRG1 | c.1866A>G p.E622= (on ENST00000405005 / NM_013964.5; = p.E627= on NM_013956.5) | Silent (SNP) | VAF 104/332 reads (31%) | catalogued as rs761969253; called by muse, mutect2, varscan2
- SSTR5 | c.306G>A p.A102= | Silent (SNP) | VAF 180/398 reads (45%) | catalogued as rs1354513472; called by muse, mutect2, varscan2
- TRIM16L | c.588C>T p.F196= | Silent (SNP) | VAF 117/285 reads (41%) | catalogued as rs775059659, COSV67459427; called by muse, mutect2, varscan2
- VSTM4 | c.309G>A p.E103= | Silent (SNP) | VAF 150/513 reads (29%) | catalogued as rs145644785; called by muse, mutect2, varscan2
- KCNC1 | chr11:17779466 G>A | 3'Flank (SNP) | VAF 76/185 reads (41%) | called by muse, mutect2, varscan2
- TRDV2 | chr14:22423042 ins GAT | 3'Flank (INS) | VAF 39/155 reads (25%) | called by mutect2, pindel, varscan2
